Somatic mutation profile of tumor specimen TCGA-16-1460-01A (aliquot TCGA-16-1460-01A-01W-0643-08) from TCGA case TCGA-16-1460, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.2 years (13,208 days).
Specimen TCGA-16-1460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed7db004-fa9a-4f64-8c94-8538d692eef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-1460-10A (Blood Derived Normal), aliquot TCGA-16-1460-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147d062c-734c-4c7e-aa89-44881e425946

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 269/509 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 102/126 reads (81%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGXT2 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 359/1222 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV99183704; called by muse, mutect2, varscan2
- ANKRD10 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 41/449 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99941035; called by muse, mutect2
- APOB | c.13240C>G p.L4414V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV51930963, COSV99263643; called by muse, mutect2, varscan2
- ATRX | c.3859del p.D1287Mfs*59 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as COSV100971714; called by mutect2, pindel, varscan2
- BAZ2B | c.4708G>T p.D1570Y | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100600381; called by muse, varscan2
- BLM | c.3445C>A p.L1149M | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100756939; called by muse, mutect2
- CD101 | c.2094C>A p.S698R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV99869144; called by muse, mutect2
- DYRK2 | c.1746G>T p.Q582H (on ENST00000344096 / NM_006482.3; = p.Q509H on NM_003583.4) | Missense Mutation (SNP) | VAF 27/860 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100165188; called by muse, mutect2
- ENTHD1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100288453; called by muse, mutect2
- ERMP1 | c.2518G>C p.A840P | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV53038575, COSV99284412; called by muse, mutect2, varscan2
- GJD4 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 141/298 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781750287, COSV58703078; called by muse, mutect2, varscan2
- H3C7 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV55099451; called by muse, mutect2, varscan2
- HHAT | c.1390+1G>A p.X464_splice | Splice Site (SNP) | VAF 26/958 reads (3%) | catalogued as COSV99802657; called by muse, mutect2
- HSD17B4 | c.699T>G p.D233E (on ENST00000414835 / NM_001199291.3; = p.D208E on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/419 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99819518; called by muse, mutect2, varscan2
- KLHL31 | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.887); catalogued as COSV100911725; called by muse, mutect2, varscan2
- KLHL38 | c.1133G>T p.S378I | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100384252, COSV58087998; called by muse, mutect2, varscan2
- LRP5 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs199887400, COSV53723041; called by muse, mutect2, varscan2
- LRRIQ1 | c.3805G>C p.D1269H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV101279527; called by muse, mutect2
- LSM12 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99518492; called by muse, mutect2, varscan2
- MAFF | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100633060; called by muse, mutect2
- MMP13 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782584939, COSV52823673; called by muse, mutect2, varscan2
- NIN | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 29/766 reads (4%) | catalogued as COSV55392062, COSV55399618, COSV99813728; called by muse, mutect2
- PPP2R5B | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV99375848; called by muse, mutect2, varscan2
- PTPRZ1 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 228/686 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV101099592; called by muse, mutect2, varscan2
- RASEF | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100906783; called by muse, mutect2, varscan2
- RUVBL2 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55484141; called by muse, mutect2
- SACS | c.3604G>A p.V1202I | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV101207174; called by muse, mutect2
- SERTAD2 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100512106; called by muse, mutect2
- SHPRH | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99261317; called by muse, mutect2, varscan2
- SPATS2 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100423368; called by muse, mutect2, varscan2
- TEX26 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779843246, COSV100994024; called by muse, mutect2, varscan2
- THNSL2 | c.231del p.I77Mfs*19 | Frame Shift Del (DEL) | VAF 36/242 reads (15%) | catalogued as COSV59082332; called by mutect2, pindel, varscan2
- TRAPPC8 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99350565; called by muse, mutect2, varscan2
- TRIM68 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331618; called by muse, mutect2
- TRPM7 | c.4096C>T p.R1366* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as rs1224629019, COSV100539400; called by muse, mutect2, varscan2
- TTC39B | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.819); catalogued as rs375664533; called by muse, mutect2, varscan2
- TTN | c.92425G>A p.V30809I (on ENST00000591111; = p.V23385I on NM_003319.4) | Missense Mutation (SNP) | VAF 215/1074 reads (20%) | PolyPhen benign (0.192); catalogued as rs397517769, COSV59977913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR3 | c.4053C>A p.F1351L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.219); catalogued as COSV99773198; called by muse, mutect2
- VPS13B | c.7733C>A p.A2578E | Missense Mutation (SNP) | VAF 60/669 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100660888; called by muse, mutect2
- ZNF470 | c.1976G>A p.S659N | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100401081; called by muse, mutect2, varscan2
- CC2D1B | c.657T>G p.D219E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- CKAP2 | c.225_234+1del p.X75_splice (on ENST00000378037 / NM_001098525.2; = p.X74_splice on NM_018204.5) | Splice Site (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- FIBP | c.925_927del p.K309del (on ENST00000338369 / NM_198897.2; = p.K302del on NM_004214.5) | In Frame Del (DEL) | VAF 28/51 reads (55%) | called by mutect2, pindel, varscan2
- OR52J3 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- XPO1 | c.2479T>C p.F827L | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- ADGRG4 | c.7686C>T p.A2562= | Silent (SNP) | VAF 71/223 reads (32%) | catalogued as rs1466872406, COSV99794401; called by muse, mutect2, varscan2
- ALDH9A1 | c.945C>T p.G315= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV100699275; called by muse, mutect2
- KCNAB3 | c.432C>T p.L144= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as COSV100366401; called by muse, mutect2, varscan2
- LRBA | c.8191T>C p.L2731= | Silent (SNP) | VAF 247/788 reads (31%) | catalogued as COSV100840964; called by muse, mutect2, varscan2
- N4BP2L2 | c.2379T>C p.A793= (on ENST00000674422; = p.A364= on NM_033111.4) | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100678758; called by muse, mutect2, varscan2
- PI4KB | c.1773G>T p.V591= (on ENST00000368873 / NM_001369623.1; = p.V603= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/623 reads (5%) | catalogued as COSV99649305; called by muse, mutect2
- RFC1 | c.252G>A p.K84= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100567442; called by muse, mutect2, varscan2
- RFX4 | c.225C>T p.V75= | Silent (SNP) | VAF 81/134 reads (60%) | catalogued as COSV100774283, COSV63503872; called by muse, mutect2, varscan2
- SLC12A5 | c.708C>A p.I236= (on ENST00000454036 / NM_001134771.2; = p.I213= on NM_020708.5) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99715388; called by mutect2, varscan2
- TMEM91 | c.300C>A p.V100= | Silent (SNP) | VAF 36/1385 reads (3%) | catalogued as COSV99652587; called by muse, mutect2
- TRPM6 | c.861G>C p.P287= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100665384; called by muse, mutect2, varscan2
- TUBA4A | c.828C>A p.I276= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as COSV99944610; called by muse, mutect2, varscan2
- UNC45A | c.637C>T p.L213= | Silent (SNP) | VAF 12/375 reads (3%) | catalogued as rs1324170831, COSV101265700; called by muse, mutect2
- ZNF573 | c.1965C>T p.A655= (on ENST00000536220 / NM_001172692.1; = p.A597= on NM_152360.3) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100265439; called by muse, mutect2, varscan2
- ATP5IF1 | c.180-44G>A | Intron (SNP) | VAF 111/267 reads (42%) | catalogued as COSV99746048; called by muse, mutect2, varscan2
